Somatic mutation profile of tumor specimen TCGA-D5-7000-01A (aliquot TCGA-D5-7000-01A-11D-1924-10) from TCGA case TCGA-D5-7000, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 79.2 years (28,913 days).
Specimen TCGA-D5-7000-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19c94938-49aa-419a-8caa-cf89b0d56056.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-7000-10A (Blood Derived Normal), aliquot TCGA-D5-7000-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d8b5a0e-0133-4146-93b0-744c229f693e

The open-access MAF lists 117 somatic variants for this specimen: 84 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 30, Nonsense Mutation 6, In Frame Del 2, RNA 2, Frame Shift Del 1, Intron 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 86/129 reads (67%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747727055, CM980134, COSV53732933, COSV53769959; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 53/103 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs121913238, COSV55502066, COSV55502677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 69/106 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABL1 | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100583364; called by muse, mutect2, varscan2
- ANKRD55 | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 50/74 reads (68%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV61946307; called by muse, mutect2, varscan2
- ARFGEF2 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 107/211 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs974192671, COSV64215151; called by muse, mutect2, varscan2
- ASTN2 | c.3158C>T p.A1053V (on ENST00000313400 / NM_001365069.1; = p.A1002V on NM_014010.5) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56003497; called by muse, mutect2, varscan2
- ATP10A | c.358G>C p.A120P | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as COSV100790781; called by muse, mutect2
- ATP1B4 | c.901A>G p.K301E (on ENST00000218008 / NM_001142447.3; = p.K297E on NM_012069.5) | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54312228; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2014C>T p.Q672* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV59474898; called by muse, mutect2, varscan2
- BCOR | c.4540C>T p.R1514* (on ENST00000378444 / NM_001123385.2; = p.R1480* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 103/189 reads (54%) | catalogued as CM0910704, COSV60703956, COSV60716852; called by muse, mutect2, varscan2
- BOD1L1 | c.505A>G p.S169G | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV99238253; called by muse, mutect2, varscan2
- BSPRY | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as rs778147226, COSV65242585; called by muse, mutect2
- CAPNS2 | c.150G>C p.E50D | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.883); catalogued as COSV50895190; called by muse, mutect2, varscan2
- CCBE1 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs374811948; called by muse, mutect2
- CDH18 | c.579C>A p.N193K | Missense Mutation (SNP) | VAF 56/77 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1396808942, COSV56917732; called by muse, mutect2, varscan2
- CFAP45 | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV63648845; called by muse, mutect2, varscan2
- CLDN2 | c.548T>A p.F183Y | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.124); catalogued as COSV61020790; called by muse, mutect2, varscan2
- COL12A1 | c.5410C>T p.R1804W | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs201973949, COSV59391669, COSV59394570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A1 | c.2293G>A p.V765I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.095); catalogued as rs200687263, COSV65424649; called by muse, mutect2, varscan2
- COQ8B | c.972G>A p.M324I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV54686698; called by muse, mutect2, varscan2
- CTNNA3 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776250185, COSV57718884, COSV57721946; called by muse, mutect2, varscan2
- DBF4 | c.1384C>T p.L462F | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV55995870, COSV55998047; called by muse, mutect2
- DIS3L | c.2744C>A p.P915Q (on ENST00000319212 / NM_001143688.3; = p.P832Q on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV56019550, COSV99972238; called by muse, mutect2, varscan2
- EP400 | c.4318C>T p.R1440C | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1473681078, COSV57770284; called by muse, mutect2, varscan2
- EXD3 | c.253C>A p.Q85K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV59806583; called by muse, mutect2, varscan2
- FAT1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439256953, COSV101499462, COSV71673513; called by muse, mutect2, varscan2
- FGF13 | c.222C>A p.Y74* | Nonsense Mutation (SNP) | VAF 36/119 reads (30%) | catalogued as COSV59544867; called by muse, mutect2, varscan2
- FLNA | c.6602G>A p.R2201H (on ENST00000369850 / NM_001110556.2; = p.R2193H on NM_001456.3) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.121); catalogued as rs368547421, COSV61041891; called by muse, mutect2, varscan2
- GAS2L2 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs781917339; called by muse, mutect2, varscan2
- HEATR4 | c.1987-2del p.X663_splice | Splice Site (DEL) | VAF 8/30 reads (27%) | catalogued as COSV58572059; called by mutect2, pindel, varscan2
- HOXA6 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs774234211, COSV56072895; called by muse, mutect2, varscan2
- IL6ST | c.1057A>G p.T353A | Missense Mutation (SNP) | VAF 84/128 reads (66%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV61140921; called by muse, mutect2, varscan2
- ITPKA | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs772076582, COSV53027408; called by muse, mutect2, varscan2
- KIAA0825 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 99/149 reads (66%) | catalogued as COSV56951063; called by muse, mutect2, varscan2
- KRTAP4-5 | c.183C>A p.C61* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV58351818, COSV58352121; called by muse, mutect2, varscan2
- LAMA1 | c.1462G>C p.G488R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101054807; called by mutect2, varscan2
- LRCH2 | c.639G>C p.E213D | Missense Mutation (SNP) | VAF 130/251 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV57749434; called by muse, mutect2, varscan2
- LRFN5 | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150445484; called by muse, mutect2, varscan2
- LRRC8E | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs748956991, COSV60717785; called by muse, mutect2, varscan2
- LSR | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs775741599, COSV61555905; called by muse, mutect2
- MCF2 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 82/372 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs368001722, COSV58481726; called by muse, mutect2, varscan2
- NAV3 | c.526T>G p.F176V | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV99886516; called by muse, mutect2, varscan2
- NDNF | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV65633238; called by muse, mutect2, varscan2
- NOTCH3 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775584737, COSV54625419; called by muse, mutect2, varscan2
- NUP88 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV52584551; called by muse, mutect2, varscan2
- OBSL1 | c.1517C>G p.T506R | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV54717734; called by muse, mutect2, varscan2
- OR5T3 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57380320, COSV57380699; called by muse, mutect2, varscan2
- OSBPL2 | c.1213C>T p.R405C (on ENST00000313733 / NM_144498.4; = p.R393C on NM_014835.4) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58216287; called by muse, mutect2, varscan2
- OTUD5 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV50235023, COSV50235876; called by muse, mutect2, varscan2
- P2RY4 | c.161C>G p.A54G | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV65736459; called by muse, mutect2, varscan2
- PCLO | c.14165G>A p.R4722Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs948339234, COSV61628998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIP5K1C | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs201265525, COSV58951894; called by muse, mutect2, varscan2
- PKN2 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 95/285 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as COSV100281281; called by muse, mutect2, varscan2
- PLXNA1 | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV52525318; called by muse, mutect2, varscan2
- PPFIA4 | c.2104_2106del p.P702del (on ENST00000447715; = p.P703del on NM_001304331.2 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 11/53 reads (21%) | catalogued as rs1206625533; called by pindel, varscan2
- PRDX2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as rs369634820; called by muse, mutect2, varscan2
- PRKCG | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs778748565, COSV54726982; called by muse, mutect2, varscan2
- PTPN5 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as rs755061119, COSV62125678; called by muse, mutect2, varscan2
- RPS6KA3 | c.996G>T p.W332C | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV65387622; called by muse, mutect2, varscan2
- RPTN | c.332G>T p.C111F | Missense Mutation (SNP) | VAF 152/462 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100285206; called by muse, mutect2, varscan2
- SAMD8 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763665486, COSV65509571; called by muse, mutect2, varscan2
- SCN9A | c.1054T>A p.L352I | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57607586; called by muse, mutect2, varscan2
- SERPINC1 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs199895690, COSV62929241; called by muse, mutect2, varscan2
- SLC2A2 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs966895511, COSV100049036; called by muse, mutect2, varscan2
- TAT | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs750638957, COSV63532687; called by muse, mutect2, varscan2
- TMBIM6 | c.11T>C p.F4S | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV57279332; called by muse, mutect2, varscan2
- TMEM161B | c.801A>T p.Q267H | Missense Mutation (SNP) | VAF 109/166 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56930683; called by muse, mutect2, varscan2
- TMPRSS9 | c.1985T>C p.I662T (on ENST00000648592; = p.I628T on NM_182973.2) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100210995; called by muse, mutect2
- TNIP3 | c.963G>C p.K321N | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.814); catalogued as COSV50247308, COSV99284261, COSV99284633; called by muse, mutect2, varscan2
- TNS4 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.02); catalogued as COSV99563519; called by muse, mutect2, varscan2
- TPCN1 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.82); PolyPhen benign (0.015); catalogued as rs368144508; called by muse, mutect2, varscan2
- TTN | c.63272C>T p.S21091L (on ENST00000591111; = p.S13667L on NM_003319.4) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | PolyPhen possibly damaging (0.455); catalogued as rs727505352, COSV59896018; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- VIRMA | c.1649G>A p.G550D | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as COSV52584415; called by muse, mutect2, varscan2
- VPS13B | c.6604C>T p.R2202C | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs756143690, COSV100663489, COSV62139584; called by muse, mutect2, varscan2
- WASF3 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs770387834, COSV58962572; called by muse, mutect2, varscan2
- WDR89 | c.994C>A p.Q332K | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0.023); catalogued as COSV99962324; called by muse, mutect2, varscan2
- XPNPEP2 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs371093861, COSV64367765; called by muse, mutect2, varscan2
- IGHV4-28 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 79/657 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IGHV4-31 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- KDM6A | c.1365dup p.S456Vfs*29 | Frame Shift Ins (INS) | VAF 191/436 reads (44%) | called by mutect2, pindel, varscan2
- PIK3CB | c.1573_1575del p.N525del | In Frame Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- UBR4 | c.14311del p.L4771Cfs*7 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- CACNA1A | c.5727C>T p.A1909= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV64196434; called by muse, mutect2, varscan2
- DBF4 | c.1386T>A p.L462= | Silent (SNP) | VAF 72/158 reads (46%) | catalogued as COSV55996597; called by muse, mutect2
- EFS | c.1245G>A p.A415= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs746664828, COSV53732056; called by muse, mutect2, varscan2
- EXOC3L4 | c.996C>T p.R332= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV66295478; called by muse, mutect2, varscan2
- FGD1 | c.822C>T p.D274= | Silent (SNP) | VAF 48/183 reads (26%) | catalogued as rs762455009, COSV100911045, COSV64308558; ClinVar: likely benign; called by muse, mutect2, varscan2
- FLYWCH1 | c.228C>T p.L76= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs183328490, COSV54145389; called by muse, mutect2, varscan2
- GPR37L1 | c.921C>T p.N307= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as rs368966314; called by muse, mutect2, varscan2
- HAUS4 | c.579C>T p.T193= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs757616950, COSV52827229; called by muse, mutect2, varscan2
- HIC2 | c.1641C>T p.T547= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs140024772; called by muse, mutect2, varscan2
- HMCN1 | c.4344G>T p.V1448= | Silent (SNP) | VAF 35/135 reads (26%) | catalogued as COSV54895372; called by muse, mutect2, varscan2
- HTR5A | c.588C>T p.R196= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV55282570; called by muse, mutect2, varscan2
- KRAS | c.180T>C p.G60= | Silent (SNP) | VAF 52/103 reads (50%) | catalogued as COSV55499291, COSV55523567, COSV99782811; called by muse, mutect2, varscan2
- LILRB3 | c.387G>T p.L129= | Silent (SNP) | VAF 78/379 reads (21%) | called by muse, mutect2, varscan2
- MAP4K4 | c.1614G>A p.Q538= (on ENST00000347699 / NM_001242559.2; = p.Q507= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as COSV56330097; called by muse, mutect2, varscan2
- NAALADL2 | c.945C>T p.S315= | Silent (SNP) | VAF 86/229 reads (38%) | catalogued as rs1230121035, COSV101379858; called by muse, mutect2, varscan2
- NHLRC1 | c.855G>C p.L285= | Silent (SNP) | VAF 34/47 reads (72%) | catalogued as rs375475285, COSV100513576; called by muse, mutect2, varscan2
- NLGN4X | c.285C>T p.S95= | Silent (SNP) | VAF 46/197 reads (23%) | catalogued as COSV52015149; called by muse, mutect2, varscan2
- OR4L1 | c.30C>T p.T10= | Silent (SNP) | VAF 51/173 reads (29%) | catalogued as rs370799664, COSV59849271; called by muse, mutect2, varscan2
- PARP15 | c.1239C>T p.A413= (on ENST00000464300 / NM_001113523.3; = p.A179= on NM_152615.2) | Silent (SNP) | VAF 54/164 reads (33%) | catalogued as rs766158836, COSV59972347; called by muse, mutect2, varscan2
- PCDHB3 | c.1554G>A p.S518= | Silent (SNP) | VAF 83/146 reads (57%) | catalogued as COSV50564013; called by muse, varscan2
- PCDHGC4 | c.459G>A p.P153= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as rs1335265010, COSV52748430; called by muse, mutect2, varscan2
- PODN | c.1770C>T p.F590= (on ENST00000395871; = p.F542= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1276343948, COSV57012423; called by muse, mutect2, varscan2
- RPH3A | c.1398C>T p.H466= (on ENST00000389385 / NM_001143854.2; = p.H462= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs139257569; called by muse, varscan2
- SASH1 | c.3171G>A p.P1057= | Silent (SNP) | VAF 22/29 reads (76%) | catalogued as rs983220877, COSV66561131; called by muse, mutect2, varscan2
- SLC18A2 | c.12C>T p.S4= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV53690176; called by muse, mutect2
- STAB2 | c.2988C>T p.N996= | Silent (SNP) | VAF 85/157 reads (54%) | catalogued as rs182793026, COSV66338099; called by muse, mutect2, varscan2
- TRRAP | c.1581C>T p.F527= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs138096391; called by muse, varscan2
- WNK2 | c.591C>T p.F197= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV52939674; called by muse, mutect2, varscan2
- WNT2 | c.1059C>T p.N353= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as rs146785086; called by muse, mutect2, varscan2
- WWP2 | c.1194G>A p.S398= | Silent (SNP) | VAF 76/183 reads (42%) | catalogued as rs770749820, COSV100598397, COSV63126188; called by muse, mutect2, varscan2
- AC005863.1 | n.209G>C | RNA (SNP) | VAF 42/121 reads (35%) | called by muse, mutect2, varscan2
- MIR512-2 | n.6T>C | RNA (SNP) | VAF 55/190 reads (29%) | called by muse, mutect2, varscan2
- MSR1 | c.1033+2516C>G | Intron (SNP) | VAF 12/61 reads (20%) | catalogued as rs1008097751, COSV100028321, COSV50517422; called by muse, mutect2
